Somatic mutation profile of tumor specimen TCGA-FD-A5BS-01A (aliquot TCGA-FD-A5BS-01A-21D-A26M-08) from TCGA case TCGA-FD-A5BS, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 68.3 years (24,963 days).
Specimen TCGA-FD-A5BS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb75cec0-8aaa-4ff7-b494-924d8dfe1bca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A5BS-10A (Blood Derived Normal), aliquot TCGA-FD-A5BS-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c07477fa-9c8a-4986-bf73-698114ef3a15

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG5 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV53507327, COSV99523788; called by muse, mutect2
- ASAH1 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.495); catalogued as COSV50501972, COSV50504395; called by muse, mutect2
- BMP7 | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs760406190, COSV67782571; called by muse, mutect2
- EPS15L1 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs201102412, COSV50167441; called by muse, mutect2
- FARP1 | c.2687C>T p.S896L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.542); catalogued as rs745947051, COSV60335087; called by muse, mutect2, varscan2
- HIVEP2 | c.2668G>A p.E890K | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50014104, COSV99174680; called by muse, mutect2
- HOATZ | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV60442474; called by muse, mutect2, varscan2
- KLRB1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144231382, COSV99037916, COSV99987382; called by muse, varscan2
- POLR1A | c.5071G>A p.D1691N | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55699476; called by muse, mutect2
- POSTN | c.2297C>G p.S766C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.77); catalogued as COSV65714627; called by muse, mutect2, varscan2
- RB1CC1 | c.1843C>A p.L615I | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99212496; called by muse, mutect2
- SERPINE1 | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 15/187 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1356660327, COSV56169448, COSV56171409; called by muse, mutect2
- STX6 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV51113985; called by muse, mutect2, varscan2
- TOX3 | c.280C>G p.P94A | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99567876, COSV99568002; called by muse, mutect2
- ZFP41 | c.404G>C p.R135T | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV58088386; called by muse, mutect2
- ZNF425 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1443982948, COSV65201028; called by muse, mutect2
- ZNF438 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV59200673; called by muse, mutect2
- CSMD1 | c.2219T>A p.I740K (on ENST00000520002; = p.I739K on NM_033225.6) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2
- DDB2 | c.714C>T p.L238= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as COSV57038873, COSV99921749; called by muse, mutect2
- FASTKD5 | c.2280C>T p.F760= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as COSV53909497; called by muse, mutect2
- RASA3 | c.1149C>T p.T383= | Silent (SNP) | VAF 16/201 reads (8%) | catalogued as COSV61873289; called by muse, mutect2
- SLC12A5 | c.3000G>A p.Q1000= (on ENST00000454036 / NM_001134771.2; = p.Q977= on NM_020708.5) | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as rs1360690829; called by muse, mutect2
- SLC22A1 | c.1347C>T p.I449= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV61453966; called by muse, mutect2
- AL162726.3 | n.255+83221G>A | Intron (SNP) | VAF 13/283 reads (5%) | catalogued as rs1420267204; called by muse, mutect2
